Somatic mutation profile of tumor specimen TCGA-85-8352-01A (aliquot TCGA-85-8352-01A-31D-2323-08) from TCGA case TCGA-85-8352, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.9 years (24,788 days).
Specimen TCGA-85-8352-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbfc29a3-7e70-477d-a49d-dd6d6c74919a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8352-10A (Blood Derived Normal), aliquot TCGA-85-8352-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/562b9ec5-8d18-4160-b696-0303137c0797

The open-access MAF lists 283 somatic variants for this specimen: 232 protein-altering or splice-affecting, 48 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 48, Nonsense Mutation 16, Splice Site 11, Frame Shift Del 7, Frame Shift Ins 3, In Frame Del 3, Splice Region 2, 5'UTR 1, RNA 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 20/35 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51644507, COSV51647552; called by muse, mutect2, varscan2
- TP53 | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 59/61 reads (97%) | hotspot (GDC flag); catalogued as CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, mutect2, varscan2
- ACSL5 | c.754C>T p.P252S (on ENST00000354273; = p.P308S on NM_016234.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100634831; called by muse, mutect2, varscan2
- ACTL6B | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.265); catalogued as COSV99355781; called by muse, mutect2, varscan2
- AK5 | c.660T>G p.F220L (on ENST00000354567 / NM_174858.3; = p.F194L on NM_012093.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100481579; called by muse, mutect2, varscan2
- AK8 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100050585; called by muse, mutect2, varscan2
- AKR1B15 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101423410; called by muse, mutect2, varscan2
- ANKRD30A | c.647G>T p.G216V (on ENST00000611781; = p.G160V on NM_052997.2) | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773270304, COSV100654523, COSV64619253; called by muse, mutect2, varscan2
- AP3D1 | c.2226G>T p.R742S | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV100643093, COSV61432069; called by muse, mutect2, varscan2
- ARGFX | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100544234; called by muse, mutect2, varscan2
- ARHGAP30 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.831); catalogued as COSV100920542; called by muse, mutect2, varscan2
- ATP13A2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs761338717, COSV58700391; called by muse, mutect2, varscan2
- ATRNL1 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 46/137 reads (34%) | catalogued as COSV100747057; called by muse, mutect2, varscan2
- B4GALT6 | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99380396; called by mutect2, varscan2
- BDKRB1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV53706229; called by muse, mutect2, varscan2
- C11orf24 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 585/672 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV100422754; called by muse, mutect2, varscan2
- C2CD5 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 133/216 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100449098; called by muse, mutect2, varscan2
- C7 | c.1660A>T p.R554W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100496688; called by muse, mutect2, varscan2
- CAD | c.3970A>G p.N1324D | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.169); catalogued as COSV99255895; called by muse, mutect2, varscan2
- CAND1 | c.3238G>C p.D1080H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101607359; called by muse, mutect2, varscan2
- CATSPERD | c.732C>A p.D244E | Missense Mutation (SNP) | VAF 199/325 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV101062824; called by muse, mutect2, varscan2
- CDH6 | c.2311G>T p.G771* | Nonsense Mutation (SNP) | VAF 105/163 reads (64%) | catalogued as COSV99421036; called by muse, mutect2, varscan2
- CDH8 | c.1951C>A p.P651T | Missense Mutation (SNP) | VAF 113/125 reads (90%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs763969712; called by muse, mutect2, varscan2
- CDK15 | c.1009+1G>C p.X337_splice (on ENST00000652192 / NM_001366386.2; = p.X286_splice on NM_139158.2) | Splice Site (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99643778; called by muse, mutect2, varscan2
- CEBPE | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923787623, COSV52829648; called by muse, mutect2, varscan2
- CEP112 | c.1230C>G p.I410M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV101211183; called by muse, mutect2, varscan2
- CEP162 | c.1200_1202del p.Q400del | In Frame Del (DEL) | VAF 46/191 reads (24%) | catalogued as rs758943409; called by pindel, varscan2
- CFAP65 | c.5260T>C p.Y1754H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as COSV100446006; called by muse, mutect2, varscan2
- CFH | c.2576A>T p.Q859L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100810281; called by muse, mutect2, varscan2
- CFHR5 | c.1411G>C p.G471R | Missense Mutation (SNP) | VAF 121/215 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750401965, COSV99889852; called by muse, mutect2, varscan2
- CHIA | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100588883, COSV58473972; called by muse, mutect2, varscan2
- CLPP | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99832262; called by muse, mutect2, varscan2
- CMSS1 | c.323T>C p.L108S | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101375652; called by muse, mutect2, varscan2
- COL12A1 | c.1891+1G>T p.X631_splice | Splice Site (SNP) | VAF 21/118 reads (18%) | catalogued as COSV100486663; called by muse, mutect2, varscan2
- COL14A1 | c.3055A>T p.I1019F | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99920894; called by muse, mutect2, varscan2
- CPS1 | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as CM114395, COSV99244260; called by muse, mutect2, varscan2
- CRNKL1 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1201689608, COSV99846805; called by muse, mutect2, varscan2
- CRX | c.101-1G>A p.X34_splice | Splice Site (SNP) | VAF 47/136 reads (35%) | catalogued as COSV99704666; called by muse, mutect2, varscan2
- CSMD2 | c.3691G>T p.G1231W | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99596110; called by muse, mutect2, varscan2
- CSMD3 | c.7906A>T p.K2636* (on ENST00000297405 / NM_001363185.1; = p.K2532* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99849528; called by muse, mutect2, varscan2
- CSMD3 | c.7019G>T p.W2340L (on ENST00000297405 / NM_001363185.1; = p.W2236L on NM_052900.3) | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99849532; called by muse, mutect2, varscan2
- DDX27 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361880007, COSV100873588; called by muse, mutect2, varscan2
- DDX60L | c.1762G>T p.D588Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV99488588; called by muse, mutect2, varscan2
- DEUP1 | c.1781A>G p.K594R | Missense Mutation (SNP) | VAF 76/82 reads (93%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.586); catalogued as COSV99977692; called by muse, mutect2, varscan2
- DGKI | c.3053G>T p.G1018V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99937573; called by muse, mutect2, varscan2
- DGKI | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1022366205, COSV99937575; called by muse, mutect2, varscan2
- DISP2 | c.3963T>A p.D1321E | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99140620; called by muse, mutect2, varscan2
- DISP3 | c.1326G>T p.Q442H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99610100; called by muse, mutect2, varscan2
- DOCK10 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99291917; called by muse, mutect2, varscan2
- DSC1 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99938356; called by muse, mutect2, varscan2
- DSC1 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV99938358; called by muse, mutect2, varscan2
- EFCAB3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 79/82 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100540526; called by muse, mutect2, varscan2
- ELP4 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as COSV100635921; called by muse, mutect2, varscan2
- EPB41L3 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1427577460, COSV100550475; called by muse, mutect2, varscan2
- F13A1 | c.1344T>A p.D448E | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV99344103; called by muse, mutect2, varscan2
- FANCB | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.912); catalogued as COSV100146711; called by muse, mutect2, varscan2
- FBLN5 | c.16A>C p.R6= | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99970032; called by muse, mutect2, varscan2
- FER | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99814125; called by muse, mutect2, varscan2
- FHL5 | c.505-1G>T p.X169_splice | Splice Site (SNP) | VAF 223/230 reads (97%) | catalogued as COSV100459855; called by muse, mutect2, varscan2
- FMN2 | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1347020731, COSV100147435; called by muse, mutect2, varscan2
- FRYL | c.1579G>T p.G527W | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99978349; called by muse, mutect2, varscan2
- FSTL1 | c.698G>T p.C233F | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99821038; called by muse, mutect2, varscan2
- GALNT14 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 100/106 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100205702, COSV61107078; called by muse, mutect2, varscan2
- GALNT6 | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100695683; called by muse, mutect2, varscan2
- GAP43 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV59349562; called by muse, mutect2, varscan2
- GCN1 | c.4213G>A p.V1405M | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56105172, COSV56116103; called by muse, mutect2, varscan2
- GLYATL2 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 56/60 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99780568; called by muse, mutect2, varscan2
- GOLT1A | c.74del p.G25Efs*19 | Frame Shift Del (DEL) | VAF 49/127 reads (39%) | catalogued as COSV57644368; called by mutect2, pindel, varscan2
- GPC5 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100996216, COSV65600058; called by muse, mutect2, varscan2
- GPR174 | c.134A>C p.Y45S | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.811); catalogued as COSV99338406; called by muse, mutect2, varscan2
- GPR85 | c.869T>C p.M290T | Missense Mutation (SNP) | VAF 101/184 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV99775311; called by muse, mutect2, varscan2
- GRM1 | c.1802G>A p.C601Y | Missense Mutation (SNP) | VAF 222/236 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99269375; called by muse, mutect2, varscan2
- GZMM | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 81/90 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99198878; called by muse, mutect2, varscan2
- H3C2 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.545); catalogued as rs1270004025, COSV52517864, COSV52519480; called by muse, mutect2, varscan2
- HRH3 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100420744; called by muse, mutect2, varscan2
- HTR1D | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs776156764, COSV58448643; called by muse, mutect2, varscan2
- IPO8 | c.1595-1G>A p.X532_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99805692; called by muse, mutect2, varscan2
- IQCE | c.1094G>C p.R365T | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.077); catalogued as COSV100383791; called by muse, mutect2, varscan2
- IQCG | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 111/446 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs761509940, COSV99502778; called by muse, mutect2, varscan2
- ITGA4 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99276877; called by muse, mutect2, varscan2
- ITGB2 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100186173, COSV56607426; called by muse, mutect2, varscan2
- ITGB7 | c.2104G>C p.V702L | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV99914289; called by muse, mutect2, varscan2
- KCNMB2 | c.423+1G>A p.X141_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100844060; called by muse, mutect2, varscan2
- KCNQ3 | c.1679G>T p.R560M | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101196508; called by muse, mutect2, varscan2
- KIAA1549 | c.5545G>A p.G1849R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs751078785, COSV99652241; called by muse, varscan2
- KIAA2026 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 64/66 reads (97%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99424464; called by muse, mutect2, varscan2
- KIF1A | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100242515; called by muse, mutect2, varscan2
- KIF26B | c.4484G>C p.G1495A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100833541; called by muse, mutect2, varscan2
- KLHDC1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV99365022; called by muse, mutect2, varscan2
- KMT5C | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV99726347; called by muse, mutect2, varscan2
- KNL1 | c.6291-1G>C p.X2097_splice (on ENST00000346991 / NM_170589.5; = p.X2071_splice on NM_144508.5) | Splice Site (SNP) | VAF 25/37 reads (68%) | catalogued as COSV61155266, COSV61159879; called by muse, mutect2, varscan2
- LAMA1 | c.5322G>C p.K1774N | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV101057910; called by muse, mutect2, varscan2
- LETM1 | c.1866G>C p.L622F | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100245685; called by muse, mutect2, varscan2
- LMNTD1 | c.747del p.W249Cfs*14 | Frame Shift Del (DEL) | VAF 16/28 reads (57%) | catalogued as COSV99279365; called by mutect2, pindel, varscan2
- LRFN5 | c.2038A>T p.S680C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.253); catalogued as COSV53248969, COSV99985650; called by muse, mutect2, varscan2
- LRP1B | c.6920A>C p.D2307A | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101261695; called by muse, mutect2, varscan2
- LTN1 | c.1456G>C p.V486L | Missense Mutation (SNP) | VAF 93/100 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773431339, COSV100798261, COSV63733211, COSV63733464; called by muse, mutect2, varscan2
- MAP9 | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.54); catalogued as COSV100251140, COSV60906739; called by muse, mutect2, varscan2
- MATN4 | c.1648G>A p.D550N (on ENST00000372754; = p.D509N on NM_003833.4) | Missense Mutation (SNP) | VAF 28/119 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV100637186; called by muse, mutect2, varscan2
- MEIS3 | c.823A>G p.N275D | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100520584; called by muse, mutect2, varscan2
- MMRN1 | c.2966C>G p.S989W | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV53344007, COSV99307848; called by muse, mutect2, varscan2
- MON2 | c.435+1G>C p.X145_splice | Splice Site (SNP) | VAF 27/77 reads (35%) | catalogued as COSV99743790; called by muse, mutect2, varscan2
- MORC1 | c.2609A>T p.Q870L | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV99227957; called by muse, mutect2, varscan2
- MROH2B | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV101270948; called by muse, mutect2, varscan2
- MROH2B | c.1064T>C p.I355T | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs370194636; called by muse, mutect2, varscan2
- MUC16 | c.35143G>A p.A11715T | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.013); catalogued as rs1443492480, COSV101201910; called by muse, mutect2, varscan2
- MUC16 | c.27352C>G p.Q9118E | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101201911; called by muse, mutect2, varscan2
- MYH6 | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100677050; called by muse, mutect2, varscan2
- MYO10 | c.2914G>C p.A972P | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); catalogued as COSV99946226, COSV99946391; called by muse, mutect2, varscan2
- MYO18B | c.2120C>A p.S707Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV100125400; called by muse, mutect2
- MYO5B | c.1841T>A p.V614D | Missense Mutation (SNP) | VAF 71/77 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99546449; called by muse, mutect2, varscan2
- NAPSA | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763054627, COSV99516019; called by muse, mutect2, varscan2
- NAV3 | c.6274G>T p.D2092Y (on ENST00000397909 / NM_001024383.2; = p.D2070Y on NM_014903.6) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57062138, COSV99896247; called by muse, mutect2, varscan2
- NBEA | c.5831G>T p.C1944F | Missense Mutation (SNP) | VAF 161/165 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100084744; called by muse, mutect2, varscan2
- NDN | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1324535280, COSV59359736; called by muse, mutect2
- NEBL | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs868003827, COSV65801682, COSV65804017; called by muse, mutect2, varscan2
- NES | c.4364G>T p.G1455V | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100958012, COSV63963387; called by muse, mutect2, varscan2
- NES | c.4363G>T p.G1455W | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100958013; called by muse, mutect2, varscan2
- NF1 | c.7372A>T p.R2458* (on ENST00000358273 / NM_001042492.3; = p.R2437* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 68/75 reads (91%) | catalogued as COSV100648404; called by muse, mutect2, varscan2
- NKTR | c.2218A>T p.R740* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV99236464; called by muse, mutect2, varscan2
- NLRP2 | c.1326G>T p.Q442H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99672441, COSV99672666; called by muse, mutect2, varscan2
- NLRP7 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 84/151 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100053440; called by muse, mutect2, varscan2
- NLRP8 | c.492A>G p.I164M | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs771119814, COSV99406072; called by muse, mutect2, varscan2
- NPY2R | c.62A>C p.Q21P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100279944; called by muse, mutect2, varscan2
- NUDT8 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV100039957; called by muse, mutect2, varscan2
- OAS2 | c.1136A>G p.E379G | Missense Mutation (SNP) | VAF 289/440 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100660330; called by muse, mutect2, varscan2
- OR4K13 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV100237924, COSV59859393; called by muse, mutect2, varscan2
- OR52E2 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 85/90 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100384948; called by muse, mutect2, varscan2
- OR6C6 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as rs539529734, COSV100626533; called by muse, mutect2, varscan2
- OR6N2 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100210525; called by muse, mutect2, varscan2
- OXGR1 | c.1012T>A p.*338Rext*6 | Nonstop Mutation (SNP) | VAF 32/33 reads (97%) | catalogued as COSV100037150; called by muse, mutect2, varscan2
- PADI1 | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as COSV100968608; called by muse, mutect2, varscan2
- PARP4 | c.882G>T p.V294= | Splice Region (SNP) | VAF 75/82 reads (91%) | catalogued as COSV101132116; called by muse, mutect2, varscan2
- PCDHA9 | c.1382C>A p.T461K | Missense Mutation (SNP) | VAF 138/147 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100970159; called by muse, mutect2, varscan2
- PCDHAC2 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99163414; called by muse, mutect2, varscan2
- PCDHB5 | c.1723G>T p.V575L | Missense Mutation (SNP) | VAF 147/167 reads (88%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.014); catalogued as rs1554276131, COSV50647529, COSV99169672; called by muse, mutect2, varscan2
- PDXP | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); catalogued as COSV53217027, COSV99312965; called by muse, mutect2, varscan2
- PEX2 | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV100824959; called by muse, mutect2, varscan2
- PHGDH | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs1337749248, COSV101025230; called by muse, mutect2, varscan2
- PIWIL1 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV99806985; called by muse, mutect2, varscan2
- PKHD1L1 | c.3311C>A p.P1104Q | Missense Mutation (SNP) | VAF 106/270 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.295); catalogued as rs757565015, COSV101006911; called by muse, mutect2, varscan2
- PKHD1L1 | c.4838A>G p.D1613G | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as COSV101006912; called by muse, mutect2, varscan2
- PLCL1 | c.859A>T p.I287F | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV101407314; called by muse, mutect2, varscan2
- POGLUT1 | c.729A>T p.K243N | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99809906; called by muse, mutect2, varscan2
- POM121L12 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs747363850, COSV68692362, COSV68693283; called by muse, mutect2, varscan2
- POU4F2 | c.1185C>G p.N395K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850865; called by muse, mutect2, varscan2
- PRKCZ | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV101058211; called by muse, varscan2
- PRKDC | c.11132C>T p.P3711L | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100043219; called by muse, mutect2, varscan2
- PRKG1 | c.1049C>A p.A350E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV100907514; called by muse, mutect2, varscan2
- PTPRO | c.3487G>A p.D1163N (on ENST00000281171 / NM_030667.3; = p.D1135N on NM_002848.4) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780715086, COSV99841905; called by muse, mutect2, varscan2
- QSOX1 | c.314C>G p.T105S | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as COSV100852965; called by muse, mutect2, varscan2
- RANBP17 | c.1709A>T p.K570M | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101206406; called by muse, mutect2, varscan2
- RASA1 | c.2154G>C p.M718I | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV99171053; called by muse, mutect2, varscan2
- RASA1 | c.2348A>C p.E783A | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171069; called by muse, mutect2, varscan2
- RGS3 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 101/112 reads (90%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100466038; called by muse, mutect2, varscan2
- RNF38 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99425381; called by muse, mutect2, varscan2
- RPTOR | c.577G>T p.V193F | Missense Mutation (SNP) | VAF 106/109 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100157465, COSV60810057; called by muse, mutect2, varscan2
- RTP3 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV99947005; called by muse, varscan2
- RTP3 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV99947007; called by muse, varscan2
- RYR1 | c.3518G>T p.G1173V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100617149; called by muse, mutect2, varscan2
- SCUBE1 | c.2439C>A p.N813K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100683798; called by muse, mutect2, varscan2
- SELENOP | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100736925; called by muse, mutect2, varscan2
- SH2D3C | c.1507C>A p.R503S (on ENST00000314830 / NM_170600.3; = p.R346S on NM_005489.4) | Missense Mutation (SNP) | VAF 193/211 reads (91%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100137670; called by muse, mutect2, varscan2
- SH3GL2 | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.81); catalogued as COSV101014871; called by muse, mutect2, varscan2
- SH3GLB1 | c.480A>T p.K160N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV100990828; called by muse, mutect2, varscan2
- SHC3 | c.1608G>C p.M536I | Missense Mutation (SNP) | VAF 126/137 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV101012080, COSV65439553; called by muse, mutect2, varscan2
- SLC3A1 | c.52T>A p.C18S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.058); catalogued as rs1266447016, COSV99577718; called by muse, mutect2, varscan2
- SLC44A3 | c.1565C>G p.S522* (on ENST00000271227 / NM_001114106.3; = p.S474* on NM_152369.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99598700; called by muse, mutect2, varscan2
- SLC52A3 | c.1149G>C p.M383I | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV99448443; called by muse, mutect2, varscan2
- SLCO5A1 | c.2415C>A p.H805Q | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs369365867, COSV99481160; called by muse, mutect2, varscan2
- SMARCA4 | c.2344G>T p.G782C | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759205, COSV60801274; called by muse, mutect2, varscan2
- SMCHD1 | c.5171G>A p.G1724E | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99862690; called by muse, mutect2, varscan2
- SNAP23 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99987494; called by muse, mutect2, varscan2
- SNRPA | c.585G>T p.M195I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.775); catalogued as COSV54682575, COSV99698968; called by muse, mutect2, varscan2
- SPAG17 | c.5413G>A p.V1805I | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100310764; called by muse, mutect2, varscan2
- SPTBN4 | c.4094G>T p.R1365L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV58953872, COSV58956478; called by muse, mutect2, varscan2
- ST8SIA2 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 38/174 reads (22%) | PolyPhen possibly damaging (0.734); catalogued as COSV51570206, COSV99184560; called by muse, mutect2, varscan2
- TENM3 | c.1640C>A p.A547D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.394); catalogued as COSV101305502, COSV69311877; called by muse, mutect2, varscan2
- TFDP2 | c.893A>G p.Y298C (on ENST00000489671 / NM_001178139.2; = p.Y238C on NM_006286.5) | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100051077; called by muse, mutect2, varscan2
- TGFBR2 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.35); catalogued as rs984098699, COSV55456371, COSV55458262; called by muse, mutect2, varscan2
- TLL1 | c.746G>T p.W249L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV99289334; called by muse, mutect2, varscan2
- TLL1 | c.747G>T p.W249C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99289339; called by muse, mutect2, varscan2
- TLN2 | c.2399G>C p.R800P | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV100170221, COSV60890965; called by muse, mutect2, varscan2
- TM4SF4 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV100542066; called by muse, mutect2, varscan2
- TM4SF4 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV100542068; called by muse, mutect2, varscan2
- TMEM131 | c.1838A>C p.K613T | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV99489748; called by muse, mutect2, varscan2
- TMEM252 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101051160; called by muse, mutect2, varscan2
- TOGARAM1 | c.2034G>T p.K678N | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as COSV100753323; called by muse, mutect2, varscan2
- TRPC5 | c.1198C>A p.P400T | Missense Mutation (SNP) | VAF 139/142 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99462930; called by muse, mutect2, varscan2
- TSC2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 30/32 reads (94%) | catalogued as COSV99526537; called by muse, mutect2, varscan2
- TYRP1 | c.48G>C p.L16F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV101141480; called by muse, mutect2, varscan2
- UBE3D | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99389137; called by muse, mutect2, varscan2
- UCN3 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100991749; called by muse, mutect2, varscan2
- UGGT1 | c.1476C>G p.I492M | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs139418908, COSV99391268; called by muse, mutect2, varscan2
- UGT2B10 | c.1385G>A p.W462* | Nonsense Mutation (SNP) | VAF 72/165 reads (44%) | catalogued as COSV55319683; called by muse, mutect2, varscan2
- USH2A | c.5852G>T p.G1951V | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs111598839, COSV100243322, COSV56329885; called by muse, mutect2, varscan2
- USP22 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV99820529; called by muse, mutect2, varscan2
- VN1R2 | c.823G>C p.G275R | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV100448213; called by muse, mutect2, varscan2
- VWC2 | c.827-1G>T p.X276_splice | Splice Site (SNP) | VAF 19/64 reads (30%) | catalogued as COSV61489993; called by muse, mutect2, varscan2
- WDR93 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99175862; called by muse, mutect2, varscan2
- WNT5B | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767101981, COSV100148852; called by muse, mutect2, varscan2
- WWTR1 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV100640975; called by muse, mutect2, varscan2
- YEATS2 | c.3265C>G p.L1089V | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100528365; called by muse, mutect2, varscan2
- ZBTB37 | c.935C>G p.S312C | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV100875362; called by muse, mutect2, varscan2
- ZBTB7A | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 58/83 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV100476000; called by muse, mutect2, varscan2
- ZDBF2 | c.6632A>C p.Q2211P | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100985617; called by muse, mutect2, varscan2
- ZEB1 | c.3250G>T p.G1084* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100315186; called by muse, mutect2, varscan2
- ZIC5 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1008969009, COSV57439055; called by muse, mutect2, varscan2
- ZNF112 | c.1911C>G p.F637L (on ENST00000337401 / NM_001083335.2; = p.F631L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100496352, COSV61621157; called by muse, mutect2, varscan2
- ZNF124 | c.1009A>G p.K337E (on ENST00000543802 / NM_001297568.1; = p.K275E on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100517916, COSV61506799; called by muse, mutect2, varscan2
- ZNF154 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 118/177 reads (67%) | catalogued as COSV101377553; called by muse, mutect2, varscan2
- ZNF18 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100503194; called by muse, mutect2, varscan2
- ZNF429 | c.1825A>T p.T609S | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs1311714635, COSV100642056; called by muse, mutect2, varscan2
- ZNF490 | c.218T>A p.L73* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as COSV100267553; called by muse, mutect2, varscan2
- ZNF599 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100251347; called by muse, mutect2, varscan2
- ZNF628 | c.2965A>T p.S989C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.321); catalogued as COSV99220320; called by muse, mutect2
- ZNF665 | c.734G>T p.R245I (on ENST00000600412; = p.R310I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/183 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as rs375282602; called by muse, mutect2
- ZNF804B | c.933T>A p.D311E | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100306523; called by muse, mutect2, varscan2
- ZNF99 | c.112A>T p.R38* | Nonsense Mutation (SNP) | VAF 64/70 reads (91%) | catalogued as COSV101233991; called by muse, mutect2, varscan2
- ADAM21 | c.1531_1539del p.D511_H513del | In Frame Del (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- CHD3 | c.3496-3_3525del p.X1166_splice | Splice Site (DEL) | VAF 15/122 reads (12%) | called by mutect2, pindel
- CSMD2 | c.3484del p.R1162Vfs*11 | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- H4C5 | c.26dup p.L11Tfs*3 | Frame Shift Ins (INS) | VAF 141/208 reads (68%) | called by mutect2, pindel, varscan2
- HERC2 | c.11503G>C p.V3835L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MUC2 | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 94/98 reads (96%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2
- MYT1L | c.2949del p.D985Tfs*4 | Frame Shift Del (DEL) | VAF 80/113 reads (71%) | called by mutect2, pindel, varscan2
- RGS8 | c.104del p.P35Qfs*40 (on ENST00000367556 / NM_001369564.2; = p.P53Qfs*40 on NM_033345.3) | Frame Shift Del (DEL) | VAF 52/168 reads (31%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.2239dup p.V747Gfs*14 | Frame Shift Ins (INS) | VAF 26/129 reads (20%) | called by mutect2, pindel, varscan2
- SMC5 | c.563del p.A188Vfs*31 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- SUPT16H | c.1832dup p.T612Dfs*15 | Frame Shift Ins (INS) | VAF 35/102 reads (34%) | called by mutect2, pindel, varscan2
- XKR4 | c.1791del p.I597Mfs*25 | Frame Shift Del (DEL) | VAF 49/140 reads (35%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.2518_2520del p.I840del | In Frame Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- AQP9 | c.546C>T p.S182= | Silent (SNP) | VAF 76/109 reads (70%) | catalogued as COSV99583267; called by muse, mutect2, varscan2
- ASPDH | c.537T>G p.P179= (on ENST00000389208 / NM_001114598.2; = p.P74= on NM_001024656.3) | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100976061; called by muse, mutect2, varscan2
- ATG9B | c.750C>T p.T250= | Silent (SNP) | VAF 246/444 reads (55%) | catalogued as COSV100939942; called by muse, mutect2, varscan2
- CACNB2 | c.871C>T p.L291= (on ENST00000324631 / NM_201596.3; = p.L236= on NM_000724.4) | Silent (SNP) | VAF 99/215 reads (46%) | catalogued as rs753398962, COSV99996653; called by muse, mutect2, varscan2
- CSMD3 | c.3183A>T p.P1061= (on ENST00000297405 / NM_001363185.1; = p.P957= on NM_052900.3) | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV99849540; called by muse, mutect2, varscan2
- DYRK3 | c.1368C>T p.T456= | Silent (SNP) | VAF 337/613 reads (55%) | catalogued as COSV100895849; called by muse, mutect2, varscan2
- EAPP | c.825T>C p.F275= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs1009035860, COSV99164270; called by muse, mutect2
- ENG | c.111C>T p.P37= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs755626994, COSV100785353; called by muse, mutect2, varscan2
- FBN3 | c.3822G>T p.G1274= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV99561952; called by muse, mutect2, varscan2
- FBXW7 | c.2016G>A p.V672= (on ENST00000281708 / NM_001349798.2; = p.V592= on NM_018315.5) | Silent (SNP) | VAF 48/150 reads (32%) | catalogued as COSV99661545; called by muse, mutect2, varscan2
- FGF18 | c.195C>T p.H65= | Silent (SNP) | VAF 25/28 reads (89%) | catalogued as rs778143601, COSV51127677, COSV99210065; called by muse, mutect2, varscan2
- GGA3 | c.1713C>G p.G571= (on ENST00000537686 / NM_138619.4; = p.G538= on NM_014001.5) | Silent (SNP) | VAF 59/61 reads (97%) | catalogued as COSV99822381; called by muse, mutect2, varscan2
- HECW1 | c.2190C>T p.S730= | Silent (SNP) | VAF 40/166 reads (24%) | catalogued as COSV67829274, COSV67830627; called by muse, mutect2, varscan2
- HELZ2 | c.1257G>C p.L419= | Silent (SNP) | VAF 63/69 reads (91%) | catalogued as COSV100915728; called by muse, mutect2, varscan2
- HIF3A | c.189C>T p.Y63= (on ENST00000377670 / NM_152795.4; = p.T43I on NM_022462.4) | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV99356106; called by muse, mutect2
- KMT2C | c.2907A>G p.G969= | Silent (SNP) | VAF 27/228 reads (12%) | catalogued as COSV100077219, COSV51358918; called by muse, mutect2
- MAGEA8 | c.294C>T p.S98= | Silent (SNP) | VAF 128/131 reads (98%) | catalogued as COSV99674834; called by muse, mutect2, varscan2
- NAV3 | c.2409G>A p.E803= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV57107763, COSV99896242; called by muse, mutect2, varscan2
- NDN | c.873C>A p.P291= | Silent (SNP) | VAF 17/19 reads (89%) | catalogued as COSV100086754; called by muse, mutect2
- NEUROG1 | c.282C>A p.R94= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as rs369851304, COSV100130867; called by muse, varscan2
- OAS1 | c.72G>T p.T24= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV99177312; called by muse, mutect2, varscan2
- OLFML2B | c.1566G>T p.L522= | Silent (SNP) | VAF 181/319 reads (57%) | catalogued as COSV99668998; called by muse, mutect2, varscan2
- OR2G6 | c.792T>C p.N264= | Silent (SNP) | VAF 95/156 reads (61%) | catalogued as rs758478274, COSV100598343; called by muse, mutect2, varscan2
- OR2M3 | c.360T>C p.Y120= | Silent (SNP) | VAF 316/553 reads (57%) | catalogued as rs750615241, COSV101513531; called by muse, mutect2, varscan2
- OR4K2 | c.297C>A p.T99= | Silent (SNP) | VAF 44/168 reads (26%) | catalogued as COSV53849469; called by muse, mutect2, varscan2
- OR51M1 | c.27T>A p.P9= | Silent (SNP) | VAF 113/125 reads (90%) | catalogued as COSV100150408; called by muse, mutect2, varscan2
- PCDHA8 | c.1521C>T p.Y507= | Silent (SNP) | VAF 172/182 reads (95%) | catalogued as COSV100970158; called by muse, mutect2, varscan2
- PGK2 | c.1188C>G p.G396= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as COSV100505725, COSV59163670; called by muse, mutect2, varscan2
- PIH1D1 | c.717C>T p.I239= | Silent (SNP) | VAF 83/151 reads (55%) | catalogued as rs1009227952, COSV51807077; called by muse, mutect2, varscan2
- PPA2 | c.105C>T p.Y35= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100050014; called by muse, mutect2, varscan2
- PPP1R16B | c.354G>A p.K118= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as COSV100240127; called by muse, mutect2, varscan2
- PRAMEF17 | c.1284G>A p.E428= | Silent (SNP) | VAF 95/219 reads (43%) | called by muse, mutect2, varscan2
- PRF1 | c.355C>A p.R119= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as CM074979, COSV100942691, COSV64615209; called by muse, mutect2, varscan2
- RELN | c.9279C>A p.L3093= | Silent (SNP) | VAF 59/198 reads (30%) | catalogued as COSV100635017; called by muse, mutect2, varscan2
- SAMD11 | c.648C>A p.L216= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100498204; called by muse, mutect2, varscan2
- SEMA4G | c.1479T>C p.Y493= | Silent (SNP) | VAF 130/207 reads (63%) | catalogued as rs1306051543, COSV99273274; called by muse, mutect2, varscan2
- SLC4A8 | c.2844G>A p.P948= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as rs748358954, COSV100177626; called by muse, mutect2, varscan2
- SMU1 | c.78G>T p.A26= | Silent (SNP) | VAF 74/77 reads (96%) | catalogued as COSV101238598, COSV68139505; called by muse, mutect2, varscan2
- TAB1 | c.352C>T p.L118= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as COSV99336322; called by muse, mutect2, varscan2
- TAS2R1 | c.486A>G p.Q162= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV101225883; called by muse, mutect2, varscan2
- TMEM131 | c.948T>C p.V316= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV99489752; called by muse, mutect2, varscan2
- TSR1 | c.2193G>A p.L731= | Silent (SNP) | VAF 54/82 reads (66%) | catalogued as COSV100027243, COSV100027244; called by muse, mutect2, varscan2
- USP14 | c.420G>A p.L140= | Silent (SNP) | VAF 73/117 reads (62%) | catalogued as COSV99864479; called by muse, mutect2, varscan2
- VAC14 | c.1689G>A p.E563= | Silent (SNP) | VAF 54/61 reads (89%) | catalogued as COSV99935142; called by muse, mutect2, varscan2
- WDFY3 | c.2667A>G p.E889= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV99885950; called by muse, mutect2, varscan2
- ZDHHC8 | c.1975C>A p.R659= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100273279; called by muse, mutect2, varscan2
- ZIC2 | c.1014G>T p.P338= | Silent (SNP) | VAF 89/95 reads (94%) | catalogued as COSV100891820, COSV66255558; called by muse, mutect2, varscan2
- ZNF883 | c.1071C>G p.V357= | Silent (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- PLCB1 | c.2524-6229A>C | Intron (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.642G>T | RNA (SNP) | VAF 139/231 reads (60%) | catalogued as rs745713860; called by muse, mutect2, varscan2
- RRH | c.-2A>T | 5'UTR (SNP) | VAF 31/82 reads (38%) | catalogued as COSV99902027; called by muse, mutect2, varscan2
